Surgical pathology report (de-identified scan), TCGA case TCGA-A3-A6NI, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-A6NI-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:

Accession:

Physician:

ICD-0-3
Carcinoma, renal cell
831213
Site Kidney NOS
C64.9
JW 7/12/13

PROCEDURE

Left-hand assisted laparoscopic nephrectomy.

SPECIMEN:

Left kidney.

HISTORY

Renal mass

(Stage IV chronic kidney disease with history of renal transplant)

GROSS

Received fresh in a container labeled "left kidney" is a kidney with a moderate amount of attached perinephric fat (12.5 x 8 x 4.8 cm). The kidney by itself (9.5 x 3.8 x 3.2 cm), weighs 78 grams. Hilar vessels are up to 0.8 cm long, 2.5 cm in diameter. The renal vein lumen is widely patent. The attached ureter (2.5 cm long, 0.4 cm in diameter) has a metal clip across the lumen adjacent to the margin.

The inferior pole of the kidney has a 4 cm in diameter discrete tumor nodule with a mottled, spongy orange gray cut surface. Scattered areas of hemorrhage are present throughout. The tumor has a discrete pushing margin, which produces a bulge in the overlying intact capsule. Extension into the adjacent perinephric fat is not apparent. The overlying adventitia margin is marked with black ink. Superiorly, the tumor margin is within 0.2 cm of the renal sinus fat. Direct extension into perinephric fat is not apparent. The remaining renal parenchyma has a thin, atrophic firm tan cortex (up to 0.5 cm thick) and numerous cortical cysts containing clear fluid and old, brown blood. Renal pyramids are atrophic. Major and minor calices along with the renal pelvis are lined by mildly striated gray-white mucosa.

1. Hilar vessel margins and ureter margin.
2. Inked adventitia margin.
- 3-5. Tumor.
- 6-7. Parenchyma away from tumor.
8. Renal pelvic mucosa and ureter.

MICROSCOPIC

Performed.

Printed by:

Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Surg Path Final Report

* Final Report *

DIAGNOSIS

Left kidney, nephrectomy:
Renal cell carcinoma, clear cell type.
End-stage renal disease.

CPT 88307

RENAL CARCINOMA SUMMARY:

PROCEDURE: Hand assisted laparoscopic nephrectomy.

SPECIMEN LATERALITY: Left.

TUMOR FOCALITY: Unifocal.

TUMOR SIZE: 4 cm.

MACROSCOPIC EXTENT OF TUMOR: Limited to kidney.

MICROSCOPIC EXTENT OF TUMOR: Limited to kidney.

EXTENSION INTO MAJOR RENAL VEIN: Not identified.

HISTOLOGIC TYPE: Renal cell carcinoma, clear cell type.

HISTOLOGIC GRADE (Furman): Grade 3.

SARCOMATOID FEATURES: Not identified.

MARGINS: Negative for carcinoma.

OTHER FINDINGS: End-stage kidney (marked glomerulosclerosis and tubular atrophy).

PATHOLOGIC TNM (AJCC): pT1a, pNX.

(Electronic Signature)

Completed Action List:

*

Type: Surg Path Final Report

Date:

Status:

Title: SURG PATH FINAL REPORT

Encounter info:

Printed by:

Printed on:

operative report confirms transplanted
Kidney to be (R) side - (L) kidney has
+ cga tumor - okay to process
Disqualified. TCGA tumor taken 7/12/13
from donated kidney - so normal
tissue will not match. Page 2 of 2
(End of Report) 7/8/13

Prior Malignancy History	Qualified	✓
Case is (closed)		DISQUALIFIED
Reviewed	7/12/13	

Source: NCI Genomic Data Commons file e5c25025-0975-44de-b549-f4b0fabf244e (TCGA-A3-A6NI.0498740D-7B64-4169-AA87-41F8A98CC479.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).